Somatic mutation profile of tumor specimen TARGET-30-PATYDC-01A (aliquot TARGET-30-PATYDC-01A-01D) from TARGET case TARGET-30-PATYDC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 5.3 years (1,919 days).
Specimen TARGET-30-PATYDC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07946e13-5d07-4a50-b3fd-67b8a772ccbf.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATYDC-10A (Blood Derived Normal), aliquot TARGET-30-PATYDC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb8a27f8-4bd3-4f79-9901-66e51829c2bb

The open-access MAF lists 1 somatic variant for this specimen: 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TUT4 | c.3069+56T>C | Intron (SNP) | VAF 33/82 reads (40%) | catalogued as COSV57109753; called by muse, mutect2, varscan2
